Gene-level copy-number profile of specimen HCM-CSHL-0255-C18-85F from HCMI case HCM-CSHL-0255-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G4.
Specimen HCM-CSHL-0255-C18-85F: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 34b4cb08-44c8-49a7-b116-61182aa174b9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0255-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/c2544b4c-ed6e-4a0e-a472-5387681442b7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 9,110; copy number 2: 43,067; copy number 3: 4,337; copy number 4: 1,230; copy number 5: 412; copy number 6: 151; copy number 7: 2; copy number 8: 88.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 653 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:117,139,715–117,804,174, 3 genes, copy number 5: RNU7-190P, AC092170.1, AC009312.1.
- chr13:23,134,174–28,778,937, 132 genes, copy number 6 (broad region; genes not listed).
- chr13:78,786,272–105,505,681, 269 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr13:109,400,696–114,337,626, 110 genes, copy number 5 (broad region; genes not listed).
- chr16:18,313,294–18,562,211, 19 genes, copy number 6: AC126755.3, NPIPA8, AC126755.5, PKD1P4, MIR6511A4, AC126755.4, NPIPA9, PKD1P5, MIR6770-3, Y_RNA, AC126755.2, MIR3180-3, MIR3670-3, AC126755.1, MIR3179-3, NOMO2, MIR3670-4, MIR3179-4, AC136618.2.
- chr16:30,833,626–30,910,208, 7 genes, copy number 5: BCL7C, MIR762HG, MIR4519, AC135048.2, MIR762, CTF1, CTF2P.
- chr16:31,700,590–31,711,986, 3 genes, copy number 5: CLUHP3, AC074050.4, AC074050.3.
- chr16:49,072,543–53,703,938, 110 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9,110. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
